Somatic mutation profile of tumor specimen TCGA-13-2059-01A (aliquot TCGA-13-2059-01A-01D-1526-09) from TCGA case TCGA-13-2059, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.5 years (18,449 days).
Specimen TCGA-13-2059-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f966ec7-bbce-4fc1-997f-556e8c2875ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-2059-10A (Blood Derived Normal), aliquot TCGA-13-2059-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d93858e-4f86-4eb8-bc2d-e8ebcce7a252

The open-access MAF lists 112 somatic variants for this specimen: 82 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 29, In Frame Del 4, Splice Site 3, Frame Shift Del 3, Nonsense Mutation 2, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 111/137 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs1285748183, COSV53173941; called by muse, varscan2
- AEBP1 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788472; called by muse, mutect2
- AHCTF1 | c.1910-1G>T p.X637_splice (on ENST00000366508; = p.X611_splice on NM_015446.5) | Splice Site (SNP) | VAF 5/95 reads (5%) | catalogued as COSV100403176; called by muse, mutect2
- AKR1A1 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 207/347 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0.116); catalogued as COSV61087809; called by muse, mutect2, varscan2
- AMHR2 | c.1319A>T p.Y440F | Missense Mutation (SNP) | VAF 196/532 reads (37%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.526); catalogued as COSV99143036; called by muse, mutect2
- ARGFX | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 162/1043 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV57683948; called by muse, mutect2, varscan2
- AZGP1 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 96/1272 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1269573845, COSV52798289; called by muse, mutect2
- C8B | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 116/387 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV64779967; called by muse, mutect2, varscan2
- CA3 | c.604T>G p.C202G | Missense Mutation (SNP) | VAF 165/289 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53411613; called by muse, mutect2, varscan2
- CACNA1C | c.1987A>T p.I663F | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as COSV59780046; called by muse, mutect2
- CACNA1S | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 286/984 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62935565, COSV62944526; called by muse, mutect2, varscan2
- CALCRL | c.686G>T p.W229L | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101130888; called by muse, mutect2
- CCDC112 | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65474127; called by muse, mutect2, varscan2
- CCDC141 | c.3882C>G p.F1294L | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55379124, COSV55384008; called by muse, mutect2, varscan2
- CFAP43 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99530433; called by muse, mutect2
- CFAP57 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 28/784 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100763994; called by muse, mutect2
- CHD5 | c.2161A>T p.T721S | Missense Mutation (SNP) | VAF 185/411 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV52426641; called by muse, mutect2, varscan2
- CLSTN3 | c.1240G>T p.V414F | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56940898; called by muse, mutect2, varscan2
- CYP2W1 | c.787A>T p.S263C | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1341222783, COSV58271762; called by muse, mutect2, varscan2
- DGAT1 | c.1062G>C p.Q354H | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); catalogued as COSV100183938; called by muse, mutect2, varscan2
- DISP2 | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs752510007, COSV51146789; called by muse, mutect2, varscan2
- DNAH8 | c.5170G>T p.V1724L | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59484852; called by muse, mutect2, varscan2
- DPYSL4 | c.718G>C p.V240L | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV58310232; called by muse, mutect2, varscan2
- EIF3E | c.1147A>G p.K383E | Missense Mutation (SNP) | VAF 65/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55201691; called by muse, mutect2, varscan2
- EPHB6 | c.2167G>A p.V723M | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1325114736, COSV63894036; called by muse, mutect2, varscan2
- ERBB2 | c.2567C>G p.P856R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54084589; called by muse, mutect2, varscan2
- FAM3D | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 134/435 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62559038, COSV62559704; called by muse, mutect2, varscan2
- FLG | c.3970G>A p.D1324N | Missense Mutation (SNP) | VAF 384/666 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs780192750, COSV64237347; called by muse, mutect2, varscan2
- FOXL1 | c.503C>G p.A168G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57215467; called by muse, mutect2, varscan2
- GABRA1 | c.1306T>A p.L436I | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.832); catalogued as COSV50098441, COSV50122626; called by muse, mutect2, varscan2
- GON4L | c.3425C>T p.S1142F | Missense Mutation (SNP) | VAF 73/727 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV55205873; called by muse, mutect2, varscan2
- GPR153 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV64939094; called by mutect2, varscan2
- GPR183 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 185/527 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.302); catalogued as rs373174545; called by muse, mutect2, varscan2
- GPR20 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV66685176; called by muse, mutect2, varscan2
- GRIN2B | c.2711C>T p.T904M | Missense Mutation (SNP) | VAF 83/592 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs552036402, COSV74208276; called by muse, mutect2, varscan2
- HECW2 | c.572-1G>A p.X191_splice | Splice Site (SNP) | VAF 18/294 reads (6%) | catalogued as COSV99646035, COSV99647836; called by muse, mutect2
- IKZF2 | c.1531C>G p.R511G | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV59584967; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1356T>A p.D452E | Missense Mutation (SNP) | VAF 133/175 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56306892; called by muse, mutect2, varscan2
- KCNA1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV101230135; called by muse, mutect2
- KIF21A | c.1223G>C p.R408T | Missense Mutation (SNP) | VAF 88/370 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62768081; called by muse, mutect2, varscan2
- KLHL9 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100757006; called by muse, mutect2
- KRT9 | c.706C>A p.L236M | Missense Mutation (SNP) | VAF 24/650 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV99879032; called by muse, mutect2
- LAMC3 | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63092404, COSV63095855; called by muse, mutect2, varscan2
- LTN1 | c.5235C>G p.C1745W | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63735501; called by muse, mutect2, varscan2
- MDM1 | c.650G>C p.S217T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV57449194; called by muse, mutect2, varscan2
- MYO3A | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56352107; called by muse, mutect2, varscan2
- NOP56 | c.1737C>G p.S579R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV61391886; called by muse, mutect2, varscan2
- PARD3 | c.2665T>A p.S889T | Missense Mutation (SNP) | VAF 16/397 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100400362; called by muse, mutect2
- PCSK9 | c.1859A>T p.E620V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV53780128; called by muse, mutect2, varscan2
- PDE3A | c.2796G>T p.W932C | Missense Mutation (SNP) | VAF 76/795 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100761746; called by muse, mutect2, varscan2
- PLAA | c.1411T>A p.F471I | Missense Mutation (SNP) | VAF 85/457 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV68305728; called by muse, mutect2, varscan2
- PLXNB1 | c.5279G>C p.G1760A | Missense Mutation (SNP) | VAF 61/85 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV56494752; called by muse, mutect2, varscan2
- PTPRZ1 | c.6113G>C p.S2038T | Missense Mutation (SNP) | VAF 94/607 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.2); catalogued as rs745782585, COSV66446796; called by muse, mutect2, varscan2
- RNASE6 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 117/496 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as COSV58977910; called by muse, mutect2, varscan2
- RNF213 | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.546); catalogued as COSV100173118; called by muse, mutect2
- RNF43 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 107/148 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68457580, COSV68460514; called by muse, mutect2, varscan2
- SEC23IP | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as COSV64833373; called by muse, mutect2, varscan2
- SLC16A2 | c.1106T>A p.L369H | Missense Mutation (SNP) | VAF 72/497 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV52089512; called by muse, mutect2, varscan2
- SLC24A4 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV54122587; called by muse, mutect2, varscan2
- SLC2A1 | c.107C>G p.P36R | Missense Mutation (SNP) | VAF 41/390 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as CM1111198, CM1111200, CM151868, COSV65288620; called by muse, mutect2, varscan2
- SLFN5 | c.673G>C p.G225R | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55484060; called by muse, mutect2, varscan2
- SMG6 | c.2822A>C p.Q941P | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53977738; called by muse, mutect2, varscan2
- SNTG1 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52472057; called by muse, mutect2, varscan2
- SRCAP | c.3397G>C p.V1133L | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.275); catalogued as COSV52682324; called by muse, mutect2, varscan2
- TAS2R8 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 60/642 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV99553601; called by muse, mutect2
- TDRD6 | c.1558A>C p.M520L | Missense Mutation (SNP) | VAF 85/397 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV60179302; called by muse, mutect2, varscan2
- TEP1 | c.6652G>A p.G2218R | Missense Mutation (SNP) | VAF 107/301 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53001501; called by muse, mutect2, varscan2
- TSNARE1 | c.1197G>T p.M399I | Missense Mutation (SNP) | VAF 231/321 reads (72%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56185074; called by muse, mutect2, varscan2
- UCHL3 | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 17/647 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV101111519; called by muse, mutect2
- VWA7 | c.1853G>A p.G618D | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV65174255; called by muse, mutect2, varscan2
- YES1 | c.1055C>G p.S352* | Nonsense Mutation (SNP) | VAF 71/312 reads (23%) | catalogued as COSV100099285, COSV58853661; called by muse, mutect2, varscan2
- ZNF713 | c.10G>T p.E4* (on ENST00000633730 / NM_001366796.2; = p.E17* on NM_182633.3) | Nonsense Mutation (SNP) | VAF 181/484 reads (37%) | catalogued as COSV68888467; called by muse, mutect2, varscan2
- ABCG4 | c.554_560del p.L185Hfs*4 | Frame Shift Del (DEL) | VAF 33/145 reads (23%) | called by mutect2, pindel, varscan2
- AP3S2 | c.476_484del p.A159_A161del | In Frame Del (DEL) | VAF 61/415 reads (15%) | called by mutect2, pindel
- ARHGAP21 | c.2372_2376del p.A791Efs*17 | Frame Shift Del (DEL) | VAF 44/309 reads (14%) | called by mutect2, pindel, varscan2
- CENPJ | c.4016_*45del | Nonstop Mutation (DEL) | VAF 90/408 reads (22%) | called by mutect2, pindel
- LRRN3 | c.1608_1634del p.V537_S545del | In Frame Del (DEL) | VAF 36/234 reads (15%) | called by mutect2, pindel
- PFAS | c.575-7_604del p.X192_splice | Splice Site (DEL) | VAF 46/372 reads (12%) | called by mutect2, pindel
- PRDM1 | c.1852_1902del p.L618_Q634del | In Frame Del (DEL) | VAF 34/448 reads (8%) | called by mutect2, pindel
- TAS2R13 | c.620_660del p.K207Rfs*23 | Frame Shift Del (DEL) | VAF 37/449 reads (8%) | called by mutect2, pindel
- ZNF92 | c.1263_1292del p.E422_G431del (on ENST00000328747 / NM_152626.4; = p.E353_G362del on NM_007139.4) | In Frame Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- AGRN | c.2658G>T p.L886= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as COSV65072709; called by muse, mutect2, varscan2
- AHR | c.1335T>G p.T445= | Silent (SNP) | VAF 76/544 reads (14%) | catalogued as COSV54126902; called by muse, mutect2, varscan2
- AMHR2 | c.1317C>T p.A439= | Silent (SNP) | VAF 195/530 reads (37%) | catalogued as COSV57687048, COSV99143034; called by muse, mutect2
- ATP11C | c.1494A>C p.S498= | Silent (SNP) | VAF 22/423 reads (5%) | catalogued as COSV100557480; called by muse, mutect2
- CLCA2 | c.1938A>G p.P646= | Silent (SNP) | VAF 55/415 reads (13%) | catalogued as rs751145969, COSV65289016; called by muse, mutect2, varscan2
- CLEC2D | c.405G>C p.L135= | Silent (SNP) | VAF 44/456 reads (10%) | catalogued as COSV99324882; called by muse, mutect2
- DSP | c.6207C>T p.V2069= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs147398792; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPB41L5 | c.1251G>C p.V417= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as COSV99758359; called by muse, mutect2
- GNAL | c.348C>T p.D116= (on ENST00000269162 / NM_001142339.3; = p.D193= on NM_182978.4) | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as rs770258090, COSV52335088; called by muse, mutect2, varscan2
- HFM1 | c.2295C>T p.D765= | Silent (SNP) | VAF 135/223 reads (61%) | catalogued as COSV54038550; called by muse, mutect2, varscan2
- KRT9 | c.705A>C p.T235= | Silent (SNP) | VAF 25/654 reads (4%) | catalogued as COSV99879034; called by muse, mutect2
- LCE3A | c.258G>A p.A86= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV59551272; called by mutect2, varscan2
- LRCH4 | c.1579A>C p.R527= | Silent (SNP) | VAF 13/288 reads (5%) | catalogued as COSV100052718; called by muse, mutect2
- NBN | c.123C>T p.I41= | Silent (SNP) | VAF 96/536 reads (18%) | catalogued as COSV55377587; called by muse, mutect2, varscan2
- NLRP13 | c.2070T>C p.S690= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as COSV61624378; called by muse, mutect2, varscan2
- OLFML1 | c.1122C>T p.N374= | Silent (SNP) | VAF 67/189 reads (35%) | catalogued as rs1455170431, COSV55081518, COSV55083353; called by muse, mutect2, varscan2
- OPRK1 | c.801C>T p.R267= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as rs1468745057, COSV55574732; called by muse, mutect2, varscan2
- OR52I2 | c.51C>T p.C17= | Silent (SNP) | VAF 39/309 reads (13%) | catalogued as rs773535424, COSV57046409; called by muse, mutect2, varscan2
- PCDHA1 | c.1443C>T p.D481= | Silent (SNP) | VAF 64/135 reads (47%) | catalogued as rs562316404, COSV100974280, COSV65374130; called by muse, mutect2, varscan2
- PCSK5 | c.1023C>T p.S341= | Silent (SNP) | VAF 154/662 reads (23%) | catalogued as rs370286991; called by muse, mutect2, varscan2
- PRG3 | c.177A>T p.A59= | Silent (SNP) | VAF 11/262 reads (4%) | catalogued as COSV99755796; called by muse, mutect2
- RAET1G | c.423C>T p.L141= | Silent (SNP) | VAF 111/416 reads (27%) | catalogued as rs1425235010, COSV66275309; called by muse, mutect2, varscan2
- RNF213 | c.588C>T p.F196= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100173114; called by muse, mutect2
- SERPINA10 | c.372C>A p.I124= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV56229919, COSV56229939; called by muse, mutect2, varscan2
- SYNC | c.1200G>A p.R400= | Silent (SNP) | VAF 65/222 reads (29%) | catalogued as COSV65131590; called by muse, mutect2, varscan2
- UROD | c.15G>T p.G5= | Silent (SNP) | VAF 79/513 reads (15%) | catalogued as COSV55802194; called by muse, mutect2, varscan2
- USP29 | c.804A>G p.R268= | Silent (SNP) | VAF 38/275 reads (14%) | catalogued as rs745918063, COSV54147244; called by muse, mutect2, varscan2
- ZFHX3 | c.2424G>T p.V808= | Silent (SNP) | VAF 16/334 reads (5%) | catalogued as COSV99195437; called by muse, mutect2
- ZP2 | c.933C>G p.G311= | Silent (SNP) | VAF 65/338 reads (19%) | catalogued as COSV54817378; called by muse, mutect2, varscan2
- TK2 | c.64-4867G>A | Intron (SNP) | VAF 137/253 reads (54%) | catalogued as rs1252556663, COSV55283481; called by muse, mutect2, varscan2
